Somatic mutation profile of tumor specimen TARGET-10-PARLTX-09A (aliquot TARGET-10-PARLTX-09A-01D) from TARGET case TARGET-10-PARLTX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (576 days).
Specimen TARGET-10-PARLTX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd7185d-8dbc-4168-82e6-4af453174806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLTX-10A (Blood Derived Normal), aliquot TARGET-10-PARLTX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/812513a4-4802-43a0-8cab-9b2c6aabda7f

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH17 | c.6355C>T p.Q2119* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as rs781076509; called by muse, mutect2, varscan2
- FBXO27 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as rs923431957; called by muse, mutect2, varscan2
- NRXN3 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1450875859, COSV55329252; called by muse, mutect2, varscan2
- MAF1 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- TRGJP1 | c.1_5delinsGGGGG p.T2G | Missense Mutation (ONP) | VAF 38/96 reads (40%) | called by pindel, varscan2*
- CNTNAP5 | c.1818C>T p.I606= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs374813240; called by muse, mutect2, varscan2
